Gene-level copy-number profile of tumor specimen AP-WDKZ-HV from APOLLO case AP-WDKZ, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2.
Specimen AP-WDKZ-HV: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 804b1a26-31b1-41e1-9333-f1431acb2564.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-WDKZ-QF (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/6a71bcf4-2f98-46d1-9dc3-ddaade348ec6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 116; copy number 1: 14,832; copy number 2: 37,367; copy number 3: 2,959; copy number 4: 3,364; copy number 5: 154; copy number 6: 113.

Homozygous deletions (total copy number 0; autosomes only): 116 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:53,797,764–55,074,557, 14 genes (within-gene range 0–1): AC012467.1, CHDH, IL17RB, AC012467.2, ACTR8, SELENOK, AC115282.2, CABYRP1, AC115282.1, CACNA2D3, RPS15P5, ESRG, CACNA2D3-AS1, LRTM1.
- chr9:119,495,375–120,245,050, 4 genes: AC006288.1, LINC01613, AL441989.1, MIR147A.
- chr9:134,641,803–135,907,546, 37 genes (within-gene range 0–1): COL5A1, COL5A1-AS1, AL645768.1, MIR3689C, MIR3689A, MIR3689D1, MIR3689B, MIR3689D2, MIR3689E, MIR3689F, AL603650.1, FCN2, FCN1, AL353611.1, AL353611.2, OLFM1, AL390778.1, AL390778.2, C9orf62, AL353615.1, SOCS5P2, PPP1R26-AS1, PPP1R26, C9orf116, MRPS2, AL161452.1, LCN1, OBP2A, PAEP, LINC01502, PAEPP1, AL354761.1, GLT6D1, LCN9, SOHLH1, KCNT1, CAMSAP1.
- chr9:137,605,744–137,711,018, 1 gene (within-gene range 0–1): AL590627.2.
- chr9:137,618,992–138,253,217, 13 genes (within-gene range 0–1): EHMT1, Metazoa_SRP, SETP5, AL590627.1, MIR602, AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr19:186,373–460,996, 12 genes: SEPTIN14P19, CICP19, LINC01002, RNU6-1076P, PLPP2, MIER2, AC016588.1, THEG, AC010641.1, C2CD4C, SHC2, RNA5SP462.
- chr19:13,206,442–13,633,025, 1 gene: CACNA1A.
- chr22:39,570,753–39,893,864, 5 genes: CACNA1I, ENTHD1, MTFR2P2, RN7SKP210, UQCRFS1P1.
- chr22:47,259,366–49,758,980, 29 genes: Z83836.1, Z82186.1, LINC01644, LINC00898, AL117329.1, AL117329.2, FP325330.3, FP325330.1, FP325330.2, BX284656.2, BX284656.1, MIR3201, Z82249.1, TAFA5, Z84468.1, MIR4535, LINC01310, RPL35P8, Z82202.1, C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3, AL023802.1, RN7SKP252, RPL5P35.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 267 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:116,909,916–117,138,609, 8 genes, copy number 6: PTGFRN, RNA5SP55, CD101, AL445231.1, TTF2, MIR942, TRIM45, RPS15AP9.
- chr1:154,924,740–156,248,117, 89 genes, copy number 5 (broad region; genes not listed).
- chr1:192,517,190–192,580,024, 2 genes, copy number 6: AL136987.1, RGS1.
- chr1:234,527,887–235,161,283, 24 genes, copy number 6 (within-gene range 4–6): LINC01354, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34.
- chr1:248,810,446–248,937,043, 8 genes, copy number 6: SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr6:2,765,393–3,303,373, 27 genes, copy number 5 (within-gene range 4–5): WRNIP1, SERPINB1, SERPINB9P1, MIR4645, SERPINB9, AL133351.2, AL133351.1, SERPINB6, LINC01011, NQO2, NQO2-AS1, HTATSF1P2, AL133351.4, AL133351.3, FAM136BP, SERPINB8P1, AL031963.2, RIPK1, AL031963.3, RNA5SP201, BPHL, AL031963.1, TUBB2A, TUBB2BP1, LINC02525, TUBB2B, PSMG4.
- chr6:11,154,929–11,644,343, 11 genes, copy number 6: AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP.
- chr6:16,761,138–16,766,883, 2 genes, copy number 6 (within-gene range 4–6): ATXN1-AS1, AL137003.1.
- chr6:25,962,802–26,546,933, 58 genes, copy number 6: TRIM38, U91328.2, U91328.1, U91328.3, H3P26, H1-1, H3C1, H4C1, H4C2, H3C2, H2AC4, H2BC3, H2AC5P, H3C3, H1-2, HFE, H4C3, H1-6, H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6, H4C7, H3C7, H2BC9, H3C8, H2AC10P, H2BC10, H4C8, H3C9P, BTN3A2, BTN2A2, BTN3A1, BTN2A3P, BTN3A3, BTN2A1, BTN1A1, RNU6-502P, HCG11, HMGN4.
- chr6:27,780,619–27,897,566, 20 genes, copy number 5: RSL24D1P1, H4C10P, H2BC13, H2AC13, H3C10, H2AC14, H2BC14, H4C11, H4C12, H2BC15, H2AC15, H2BC16P, H2AC16, H1-5, H3C11, H4C13, H3C12, H2AC17, H2BC17, RNU7-26P.
- chr6:112,616,703–113,084,454, 5 genes, copy number 5: PA2G4P5, AL360085.1, RNU6-1163P, AL360015.1, FCF1P10.
- chr14:18,333,726–18,412,264, 3 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2.
- chr17:59,707,192–59,892,945, 5 genes, copy number 5 (within-gene range 2–5): VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1.
- chr21:12,999,676–13,120,807, 5 genes, copy number 5: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 11,986. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
